Somatic mutation profile of tumor specimen TCGA-D1-A15X-01A (aliquot TCGA-D1-A15X-01A-11D-A122-09) from TCGA case TCGA-D1-A15X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: High Grade; Age at diagnosis: 45.3 years (16,532 days).
Specimen TCGA-D1-A15X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 439422e4-7670-4bab-9a81-dcfbaf153b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A15X-10A (Blood Derived Normal), aliquot TCGA-D1-A15X-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a595d50-fe70-4a60-84c2-23fb595e156c

The open-access MAF lists 1,921 somatic variants for this specimen: 1,385 protein-altering or splice-affecting, 506 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,264, Silent 506, Nonsense Mutation 48, Frame Shift Del 25, Splice Site 22, Splice Region 14, Intron 10, Frame Shift Ins 9, 5'Flank 6, 3'UTR 5, 3'Flank 4, RNA 3.

Variants (750 of 1,921; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 73/242 reads (30%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 93/249 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GFI1B | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554724691, COSV59745290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLRA1 | c.1283G>A p.R428H (on ENST00000455880 / NM_001146040.2; = p.R420H on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/424 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281864919, CM992338, COSV51015038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNH2 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199472971, CM055319, COSV51174893; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 93/337 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 89/286 reads (31%) | catalogued as rs777198867, CM022616, COSV60667206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3312dup p.G1105Wfs*3 | Frame Shift Ins (INS) | VAF 106/342 reads (31%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- NSD1 | c.5740C>T p.R1914C | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587784154, CM043038, COSV61777511; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3441dup p.F1148Ifs*8 | Frame Shift Ins (INS) | VAF 75/263 reads (29%) | catalogued as rs770832663; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 52/153 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 56/176 reads (32%) | catalogued as rs1210180190, CM083063, COSV57196619; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.3034C>T p.R1012* (on ENST00000591111; = p.R966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as rs397517547, CM1410919, COSV59870865; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1816T>A p.S606T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV52707238; called by muse, mutect2, varscan2
- AATK | c.2264C>T p.A755V (on ENST00000326724 / NM_001080395.3; = p.A652V on NM_004920.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs200015615, COSV58367711; called by muse, mutect2, varscan2
- ABCA12 | c.6161C>T p.A2054V (on ENST00000272895 / NM_173076.3; = p.A1736V on NM_015657.3) | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs370787997; called by muse, mutect2, varscan2
- ABCA13 | c.14431G>A p.E4811K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs758091800, COSV68947543; called by muse, mutect2, varscan2
- ABCA7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54031160; called by muse, mutect2, varscan2
- ABCB4 | c.1909A>C p.I637L | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV55936288; called by muse, mutect2, varscan2
- ABCC10 | c.4306A>T p.I1436F (on ENST00000372530 / NM_001198934.2; = p.I1408F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55088895; called by muse, mutect2, varscan2
- ABCC5 | c.1309G>T p.V437L | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV55591473; called by muse, mutect2, varscan2
- ABCC6 | c.3542G>A p.G1181D | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as rs114928628, COSV99229188; called by muse, mutect2, varscan2
- ABCG1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 114/466 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772323233, COSV59205287; called by muse, varscan2
- ABCG1 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 113/402 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV59205303; called by muse, varscan2
- ABCG1 | c.1874T>A p.I625N | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100494337; called by muse, mutect2
- ABL2 | c.851A>G p.E284G (on ENST00000502732 / NM_007314.4; = p.E269G on NM_005158.5) | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV61015323; called by muse, mutect2, varscan2
- ABT1 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as COSV51291604; called by muse, mutect2, varscan2
- AC013477.1 | c.2630C>A p.A877D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53654094; called by muse, mutect2, varscan2
- AC092143.1 | c.1828C>A p.L610M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59247982, COSV59248580; called by muse, mutect2, varscan2
- AC109583.1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 154/484 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100167862, COSV59350198, COSV59351457; called by muse, mutect2, varscan2
- AC109583.1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV59351028; called by muse, mutect2, varscan2
- ACAD10 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV58158183; called by muse, mutect2, varscan2
- ACADL | c.552A>G p.I184M | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV52053728; called by muse, mutect2, varscan2
- ACADM | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273494; called by muse, mutect2
- ACAP3 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV61222380; called by muse, mutect2, varscan2
- ACOX3 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62712323; called by muse, mutect2, varscan2
- ACTN1 | c.1892T>C p.L631P | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51993023; called by muse, mutect2, varscan2
- ACTN4 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53146756; called by muse, mutect2, varscan2
- ACTR10 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 91/237 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV54298709; called by muse, mutect2, varscan2
- ACTR5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs749402313, COSV99710124; called by muse, mutect2
- ADAM32 | c.1563A>G p.I521M | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV65950080; called by muse, mutect2, varscan2
- ADAM7 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51541047; called by muse, mutect2, varscan2
- ADAM7 | c.1552+1G>T p.X518_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | catalogued as rs971870387, COSV51541057; called by muse, mutect2, varscan2
- ADAM8 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV101291694; called by muse, varscan2
- ADAMTS13 | c.3253T>G p.S1085A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV52470444; called by muse, mutect2, varscan2
- ADAMTS17 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV51473439, COSV51482918; called by muse, varscan2
- ADAMTS17 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 54/186 reads (29%) | catalogued as rs201484140; called by muse, varscan2
- ADAMTS6 | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66860581; called by muse, mutect2, varscan2
- ADAMTSL3 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 135/404 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1439091253, COSV54451586; called by muse, mutect2, varscan2
- ADCY4 | c.2048T>A p.F683Y | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.048); catalogued as COSV60254972; called by muse, mutect2, varscan2
- ADCY9 | c.3638A>G p.Y1213C | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs914794233, COSV99570427; called by muse, mutect2
- ADCY9 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 116/406 reads (29%) | catalogued as COSV53574506, COSV53576473; called by muse, mutect2, varscan2
- ADGRF5 | c.2695A>G p.T899A | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV51935031; called by muse, mutect2, varscan2
- ADGRL1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs549520700, COSV61564825, COSV99058042; called by muse, mutect2, varscan2
- ADGRV1 | c.16295C>T p.S5432F | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs200989402, COSV67986936; called by muse, mutect2, varscan2
- ADH4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1465972449, COSV55501076; called by muse, mutect2, varscan2
- ADIPOR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs143634072; called by muse, mutect2, varscan2
- ADM | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.819); catalogued as COSV53403217; called by muse, mutect2, varscan2
- ADRA1B | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.139); catalogued as COSV60702220; called by muse, mutect2, varscan2
- AEBP1 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV56258570; called by muse, mutect2, varscan2
- AGAP3 | c.694G>A p.A232T (on ENST00000622464; = p.A268T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV58994869; called by muse, mutect2, varscan2
- AGBL4 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV61893378; called by muse, mutect2, varscan2
- AGBL5 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59936685; called by muse, mutect2, varscan2
- AGFG1 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59512461; called by muse, mutect2, varscan2
- AGGF1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57229469; called by muse, mutect2, varscan2
- AGO1 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64595517; called by muse, varscan2
- AHNAK | c.6860G>A p.S2287N | Missense Mutation (SNP) | VAF 133/458 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV57216171; called by muse, mutect2, varscan2
- AHRR | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs761134101, COSV57087418; called by muse, mutect2, varscan2
- AIRE | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV52394565; called by muse, mutect2, varscan2
- AKAP13 | c.5735G>T p.G1912V (on ENST00000394518 / NM_007200.5; = p.G1916V on NM_006738.6) | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100774063, COSV100774163; called by muse, mutect2
- AKAP13 | c.8324G>A p.G2775E (on ENST00000394518 / NM_007200.5; = p.G2779E on NM_006738.6) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63460652; called by muse, mutect2, varscan2
- AKAP9 | c.4247T>C p.F1416S | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.407); catalogued as COSV62348540; called by muse, mutect2, varscan2
- AKR7L | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV70167599; called by muse, mutect2, varscan2
- ALDH5A1 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 184/605 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV62373775; called by muse, mutect2, varscan2
- ALG13 | c.2669T>A p.V890E | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV52640035; called by muse, mutect2, varscan2
- ALOX12 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.728); catalogued as COSV52353067, COSV99278241; called by muse, mutect2
- ALOX12B | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV59873451; called by muse, mutect2, varscan2
- ALPK2 | c.5995G>A p.A1999T | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV64493757; called by muse, mutect2, varscan2
- ALPL | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs770548228, CM001060, CM138570, COSV66376303; called by muse, mutect2, varscan2
- ALS2CL | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420355279, COSV59671837, COSV59671997; called by muse, mutect2, varscan2
- ANK1 | c.2909G>A p.G970D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55883739; called by muse, mutect2, varscan2
- ANKRD11 | c.7906C>T p.H2636Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV56362654; called by muse, mutect2, varscan2
- ANKRD27 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555830097, COSV60129915; called by muse, mutect2, varscan2
- ANKRD30A | c.883G>A p.A295T (on ENST00000611781; = p.A239T on NM_052997.2) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV64612271; called by muse, mutect2, varscan2
- ANKRD52 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV57284896; called by mutect2, varscan2
- ANKRD7 | c.575+2T>C p.X192_splice | Splice Site (SNP) | VAF 63/175 reads (36%) | catalogued as COSV54555125; called by muse, mutect2, varscan2
- ANO6 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907518639, COSV57662180; called by muse, mutect2, varscan2
- ANOS1 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV52921006; called by muse, mutect2, varscan2
- ANXA1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as rs138602190; called by muse, mutect2, varscan2
- AOX1 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760074982, COSV65980752, COSV65983407; called by muse, mutect2, varscan2
- AP002748.5 | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV59149413; called by muse, mutect2, varscan2
- AP1B1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773396944, COSV58014623; called by muse, mutect2, varscan2
- AP4B1 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56725300; called by muse, mutect2, varscan2
- AP4E1 | c.1513T>C p.F505L | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55917587; called by muse, mutect2, varscan2
- APBA1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747434121, COSV55229506; called by muse, mutect2, varscan2
- APBB3 | c.896T>C p.L299P (on ENST00000357560 / NM_133173.2; = p.L306P on NM_006051.3) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60052771; called by muse, mutect2, varscan2
- APC | c.3364A>G p.N1122D | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57349838; called by muse, mutect2, varscan2
- APLP1 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs1367594825, COSV55703875; called by muse, mutect2, varscan2
- APLP1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1475297217, COSV55703883; called by muse, mutect2, varscan2
- APOBEC3C | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53326944; called by muse, mutect2, varscan2
- APOBR | c.1913G>A p.R638Q (on ENST00000431282; = p.R647Q on NM_018690.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs565646942, COSV60491308; called by muse, mutect2, varscan2
- APP | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 172/600 reads (29%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.993); catalogued as COSV60999561; called by muse, mutect2, varscan2
- APPBP2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 42/148 reads (28%) | catalogued as rs1272045451, COSV50026790, COSV50027152; called by muse, mutect2, varscan2
- AQR | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50034266; called by muse, mutect2, varscan2
- ARAP2 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as rs148859843; called by muse, mutect2, varscan2
- ARHGAP10 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 124/418 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1231124872, COSV60600586; called by muse, mutect2, varscan2
- ARHGAP10 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1204795648, COSV60600591; called by muse, mutect2, varscan2
- ARHGAP17 | c.247A>T p.T83S | Missense Mutation (SNP) | VAF 127/456 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV51508440; called by muse, mutect2, varscan2
- ARHGAP18 | c.316+2T>C p.X106_splice | Splice Site (SNP) | VAF 115/363 reads (32%) | catalogued as COSV63764645; called by muse, mutect2, varscan2
- ARHGAP22 | c.1892T>C p.L631P | Missense Mutation (SNP) | VAF 209/682 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50947319; called by muse, mutect2, varscan2
- ARHGAP33 | c.2768A>G p.N923S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.971); catalogued as COSV50125994; called by muse, mutect2, varscan2
- ARHGAP5 | c.4242G>A p.W1414* (on ENST00000345122 / NM_001030055.2; = p.W1413* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 75/293 reads (26%) | catalogued as COSV53735279; called by muse, mutect2, varscan2
- ARHGEF10 | c.3530G>A p.G1177D (on ENST00000398564; = p.G1152D on NM_014629.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1386800697, COSV50654025; called by muse, mutect2, varscan2
- ARHGEF18 | c.493+2T>C p.X165_splice (on ENST00000359920 / NM_001130955.2; = p.X61_splice on NM_015318.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 91/282 reads (32%) | catalogued as COSV60470559; called by muse, mutect2, varscan2
- ARHGEF2 | c.2458C>T p.R820C (on ENST00000361247 / NM_001162383.2; = p.R792C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1448120174; called by muse, mutect2
- ARHGEF26 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs749851646, COSV62847440; called by muse, mutect2, varscan2
- ARHGEF28 | c.4151A>G p.Y1384C | Missense Mutation (SNP) | VAF 189/568 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55258464; called by muse, mutect2, varscan2
- ARID1A | c.6707G>C p.R2236P | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV61379307; called by muse, mutect2, varscan2
- ASAH2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs565816415, COSV61483544; called by muse, mutect2, varscan2
- ASAP1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 220/700 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63049542; called by muse, mutect2, varscan2
- ASIC1 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV57318348; called by muse, mutect2, varscan2
- ASPM | c.7010C>T p.A2337V | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1274428562, COSV54131144; called by muse, mutect2, varscan2
- ASTL | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60904478; called by muse, mutect2, varscan2
- ASXL2 | c.2990A>G p.N997S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753665572, COSV99711661, COSV99711669; called by muse, mutect2
- ATF6 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV63407962; called by muse, mutect2, varscan2
- ATG9A | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1251183599, COSV63445754; called by muse, mutect2, varscan2
- ATM | c.4932G>A p.M1644I | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53749063; called by muse, mutect2, varscan2
- ATOH1 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV60038120; called by muse, mutect2, varscan2
- ATOH7 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101028469, COSV65447716; called by muse, mutect2, varscan2
- ATP10A | c.2720A>G p.D907G | Missense Mutation (SNP) | VAF 119/360 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV63518467; called by muse, mutect2, varscan2
- ATP11A | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs189256530, COSV52113694; called by muse, mutect2, varscan2
- ATP12A | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs750121465, COSV54512200; called by muse, mutect2, varscan2
- ATP1B4 | c.718T>A p.Y240N (on ENST00000218008 / NM_001142447.3; = p.Y236N on NM_012069.5) | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54313150; called by muse, mutect2, varscan2
- ATP2A2 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM099818, COSV58044914; called by muse, mutect2, varscan2
- ATP2B3 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 120/375 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54849836; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52269873; called by muse, mutect2, varscan2
- ATP8A2 | c.1271A>T p.Y424F | Missense Mutation (SNP) | VAF 138/421 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV54956175; called by muse, mutect2, varscan2
- ATP8B3 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs368521166; called by muse, mutect2, varscan2
- B3GALT4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV65851698; called by muse, mutect2, varscan2
- B3GAT1 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs768927813, COSV56998024; called by muse, mutect2, varscan2
- BAHCC1 | c.3637C>T p.R1213* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV57027784; called by muse, mutect2, varscan2
- BAHCC1 | c.5563C>T p.R1855C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs201137403; called by muse, mutect2, varscan2
- BBS10 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV53883809; called by muse, mutect2
- BBX | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV57886041; called by muse, mutect2, varscan2
- BCL11B | c.2583G>A p.M861I (on ENST00000357195 / NM_001282237.2; = p.M790I on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1266729155, COSV61736096; called by muse, mutect2, varscan2
- BCL2L1 | c.631A>G p.N211D (on ENST00000307677 / NM_001317919.2; = p.N148D on NM_001191.4) | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.272); catalogued as COSV56967895; called by muse, mutect2, varscan2
- BCORL1 | c.4973G>A p.R1658K | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as rs1569395697, COSV54390992, COSV54398079; called by muse, mutect2, varscan2
- BCR | c.2351T>C p.L784P | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100006751; called by muse, mutect2
- BDP1 | c.5910A>T p.E1970D | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1345966696, COSV62431918; called by muse, mutect2, varscan2
- BDP1 | c.7665T>A p.N2555K | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100703343; called by muse, mutect2, varscan2
- BEND4 | c.1560G>T p.Q520H | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV72469150; called by muse, mutect2, varscan2
- BICC1 | c.1541T>C p.I514T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.1); catalogued as COSV54064214; called by muse, mutect2, varscan2
- BICC1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488939371, COSV54064217; called by muse, mutect2, varscan2
- BIRC6 | c.6872G>A p.R2291H | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs551174027, COSV70200188; called by muse, mutect2, varscan2
- BIRC6 | c.7561T>C p.Y2521H | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV70200193; called by muse, mutect2, varscan2
- BLID | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs141601060, COSV73340259; called by muse, mutect2, varscan2
- BMP3 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs140292630; called by muse, mutect2, varscan2
- BMT2 | c.300T>C p.C100= | Splice Region (SNP) | VAF 134/419 reads (32%) | catalogued as COSV51777346; called by muse, mutect2, varscan2
- BRINP1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs751806082, COSV56302273; called by muse, mutect2, varscan2
- BRPF1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs756815466, COSV57405354; called by muse, mutect2, varscan2
- BRSK2 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV57544050; called by muse, mutect2, varscan2
- BSND | c.548+2T>C p.X183_splice | Splice Site (SNP) | VAF 38/115 reads (33%) | catalogued as COSV64870750; called by muse, mutect2, varscan2
- BTAF1 | c.3721C>T p.R1241* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | catalogued as COSV56431482, COSV56434966; called by muse, mutect2, varscan2
- BTBD16 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs368179412, COSV53263379; called by muse, mutect2, varscan2
- BTBD8 | c.974T>C p.I325T | Missense Mutation (SNP) | VAF 169/505 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV61546588; called by muse, mutect2, varscan2
- BTK | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.795); catalogued as COSV58120378, COSV58120554; called by muse, mutect2, varscan2
- BTN3A1 | c.955T>C p.Y319H | Missense Mutation (SNP) | VAF 134/441 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.365); catalogued as COSV50024913; called by muse, mutect2, varscan2
- BTNL8 | c.1394A>T p.E465V | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV51459267; called by muse, mutect2, varscan2
- BUD23 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.266); catalogued as COSV56095269; called by muse, mutect2, varscan2
- C12orf40 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1427700763, COSV61133280; called by muse, mutect2, varscan2
- C1QB | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV59245506; called by muse, mutect2, varscan2
- C1orf146 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV64860559; called by muse, varscan2
- C2CD2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV61599702; called by muse, mutect2, varscan2
- C2CD5 | c.1263-2A>G p.X421_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | catalogued as COSV61725072; called by muse, mutect2, varscan2
- C3 | c.4042T>G p.Y1348D | Missense Mutation (SNP) | VAF 179/555 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55574302; called by muse, mutect2, varscan2
- C3 | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754898374, COSV55574316; called by muse, mutect2, varscan2
- C3orf38 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 139/414 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs763683142, COSV59628185; called by muse, mutect2, varscan2
- C4orf45 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 136/391 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1381313614, COSV71701119; called by muse, mutect2, varscan2
- C6orf89 | c.724T>A p.L242I (on ENST00000373685; = p.L249I on NM_152734.4) | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62102079; called by muse, varscan2
- CACNA1B | c.5879C>A p.S1960Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV53129316; called by muse, mutect2, varscan2
- CACNG7 | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV55814877; called by muse, mutect2, varscan2
- CAMKK1 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs369459857; called by muse, mutect2, varscan2
- CAMKK1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV50118383; called by muse, mutect2, varscan2
- CAND1 | c.1466G>T p.S489I | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV73389644; called by muse, mutect2, varscan2
- CAP2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764904918, COSV57733064; called by muse, mutect2, varscan2
- CASP6 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 166/520 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54461019; called by muse, mutect2, varscan2
- CASZ1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs748445376, COSV59736622; called by muse, mutect2, varscan2
- CBFA2T2 | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs971756700, COSV60074373; called by muse, mutect2, varscan2
- CBFA2T3 | c.984C>G p.S328R | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV51927895; called by muse, mutect2, varscan2
- CBL | c.2033C>A p.A678D | Missense Mutation (SNP) | VAF 162/517 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV50640132, COSV50640172; called by muse, mutect2, varscan2
- CCDC114 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs561780439, COSV59557019; called by muse, mutect2, varscan2
- CCDC150 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1265761852, COSV55875136; called by muse, mutect2, varscan2
- CCDC171 | c.3566G>T p.G1189V | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52643061; called by muse, mutect2, varscan2
- CCDC180 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs768434399, COSV63830653, COSV63831225; called by muse, mutect2, varscan2
- CCDC39 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 132/452 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs747000468, COSV56485827, COSV99869095; called by muse, mutect2, varscan2
- CCDC88C | c.5197G>A p.V1733I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs369187490; called by muse, mutect2, varscan2
- CCN3 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs778838879, COSV52383450, COSV52383987; called by muse, mutect2, varscan2
- CCNO | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV57004710; called by muse, mutect2, varscan2
- CCR2 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 193/596 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.521); catalogued as COSV52749014; called by muse, mutect2, varscan2
- CCS | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774566620, COSV59578349; called by muse, mutect2, varscan2
- CD300LB | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV58725826; called by muse, mutect2, varscan2
- CDCA2 | c.2549A>G p.H850R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV57946228; called by muse, mutect2, varscan2
- CDH10 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52583735; called by muse, mutect2, varscan2
- CDH23 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV56469251; called by muse, mutect2, varscan2
- CDK11A | c.1175G>A p.G392D (on ENST00000378633 / NM_001313896.2; = p.G389D on NM_024011.4) | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.115); catalogued as COSV62265629; called by muse, mutect2, varscan2
- CDK15 | c.703C>A p.L235M (on ENST00000652192 / NM_001366386.2; = p.L184M on NM_139158.2) | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); catalogued as COSV99643010, COSV99643448; called by muse, mutect2
- CELF1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV60112566; called by muse, varscan2
- CELF6 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV54717035; called by muse, mutect2, varscan2
- CELSR2 | c.6359A>G p.N2120S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.179); catalogued as COSV54773466; called by muse, mutect2, varscan2
- CELSR3 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761096075, COSV50878434; called by muse, mutect2, varscan2
- CEMIP2 | c.1757G>C p.G586A | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as COSV65487675; called by muse, mutect2, varscan2
- CENPC | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV56623724; called by muse, mutect2, varscan2
- CENPJ | c.3062A>G p.H1021R | Missense Mutation (SNP) | VAF 191/651 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV67883553; called by muse, mutect2, varscan2
- CEP350 | c.2052G>T p.Q684H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV62603832; called by muse, mutect2, varscan2
- CFAP58 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs776932226, COSV63834448; called by muse, mutect2, varscan2
- CFAP70 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 129/417 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293127261, COSV60283831; called by muse, mutect2, varscan2
- CHD3 | c.3083G>A p.C1028Y | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57876136; called by muse, mutect2, varscan2
- CHD6 | c.4759G>A p.G1587S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1391945124, COSV64691533; called by muse, mutect2, varscan2
- CHD7 | c.3709A>G p.N1237D | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71111550; called by muse, mutect2, varscan2
- CHKB | c.533A>G p.E178G | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV56417062; called by muse, mutect2, varscan2
- CHORDC1 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs754005973, COSV57706216; called by muse, mutect2, varscan2
- CHRM5 | c.560T>C p.F187S | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67247613; called by muse, mutect2, varscan2
- CHSY3 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100519119, COSV59278660; called by muse, mutect2, varscan2
- CIP2A | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201083724; called by muse, mutect2, varscan2
- CLASP1 | c.3424T>C p.F1142L | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99755978; called by muse, mutect2
- CLASP2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56284179; called by muse, mutect2, varscan2
- CLCN7 | c.751A>C p.I251L | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51971057; called by muse, mutect2, varscan2
- CLEC1A | c.390A>C p.G130= | Splice Region (SNP) | VAF 14/250 reads (6%) | catalogued as COSV100191584; called by muse, mutect2
- CLEC4F | c.712A>G p.T238A | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55479836; called by muse, mutect2, varscan2
- CLK1 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58434087; called by muse, mutect2, varscan2
- CLOCK | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV59402404; called by muse, mutect2, varscan2
- CLPTM1L | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.05); catalogued as COSV100307193; called by muse, mutect2, varscan2
- CLRN2 | c.233del p.G78Afs*13 | Frame Shift Del (DEL) | VAF 67/233 reads (29%) | catalogued as COSV55549094; called by mutect2, pindel, varscan2
- CNGB1 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1307817307, COSV51901788; called by muse, mutect2, varscan2
- CNKSR3 | c.296T>A p.I99K | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV72161787; called by muse, mutect2, varscan2
- CNN1 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV52956193; called by muse, mutect2, varscan2
- CNNM4 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs750374054, COSV65661152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT1 | c.6632A>G p.N2211S | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1242720306, COSV55317734; called by muse, mutect2, varscan2
- CNTN3 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.056); catalogued as COSV55173777; called by muse, mutect2, varscan2
- CNTN4 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 116/373 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV68575731, COSV68584026; called by muse, mutect2, varscan2
- CNTN5 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 96/630 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99679099; called by muse, mutect2
- CNTNAP5 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV70488468; called by muse, mutect2, varscan2
- COG7 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as rs1339781797, COSV100207674; called by muse, mutect2
- COL14A1 | c.3854A>T p.D1285V | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52856986; called by muse, mutect2, varscan2
- COL16A1 | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV54707497; called by muse, mutect2, varscan2
- COL20A1 | c.251dup p.L85Pfs*30 | Frame Shift Ins (INS) | VAF 26/96 reads (27%) | catalogued as rs1441570950; called by mutect2, pindel, varscan2
- COL21A1 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 134/455 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55165792; called by muse, mutect2, varscan2
- COL22A1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57340574; called by muse, mutect2, varscan2
- COL24A1 | c.4316T>C p.I1439T | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65307738; called by muse, mutect2, varscan2
- COL24A1 | c.1694T>C p.M565T | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.142); catalogued as rs745549731, COSV65307740; called by muse, mutect2, varscan2
- COL27A1 | c.4745C>T p.S1582L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs766382533, COSV61927058; called by muse, mutect2, varscan2
- COL5A1 | c.937A>T p.T313S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100880187; called by muse, mutect2
- COL7A1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746639223, COSV60396378; called by muse, mutect2, varscan2
- COLEC12 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 124/407 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68371116; called by muse, mutect2, varscan2
- COPB1 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as COSV51448805; called by muse, mutect2, varscan2
- CORO2B | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV55953827; called by muse, mutect2, varscan2
- COX8A | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 127/459 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV58478811; called by muse, mutect2, varscan2
- CPB1 | c.494A>G p.N165S | Missense Mutation (SNP) | VAF 119/426 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.033); catalogued as COSV51574008; called by muse, mutect2, varscan2
- CPEB2 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.376); catalogued as COSV52592320, COSV99470674; called by muse, mutect2, varscan2
- CPSF1 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs202001609, COSV58233852; called by muse, mutect2, varscan2
- CPSF4 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs371928827; called by muse, mutect2, varscan2
- CR2 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100889686, COSV65508024; called by muse, mutect2, varscan2
- CREB3L4 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55132272; called by muse, mutect2, varscan2
- CREBBP | c.5698C>G p.P1900A | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52126519; called by muse, mutect2, varscan2
- CREBBP | c.3114A>G p.I1038M | Missense Mutation (SNP) | VAF 348/1070 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1300594483, COSV52126529; called by muse, mutect2, varscan2
- CRLF2 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 129/412 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV67493832; called by muse, mutect2, varscan2
- CRX | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV55759853; called by muse, mutect2
- CSE1L | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53702415; called by muse, mutect2, varscan2
- CSF3R | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58967774; called by muse, mutect2, varscan2
- CSMD2 | c.10432T>C p.F3478L | Missense Mutation (SNP) | VAF 91/353 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.297); catalogued as COSV53919739; called by muse, mutect2, varscan2
- CSMD2 | c.7561G>A p.E2521K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.403); catalogued as rs1177028383, COSV53919753; called by muse, mutect2, varscan2
- CSMD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs761180145, COSV53892340; called by muse, mutect2, varscan2
- CSNK2A1 | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV53935461; called by muse, mutect2, varscan2
- CSTF2T | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 165/536 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV58656669; called by muse, mutect2, varscan2
- CTTNBP2 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV50408690; called by muse, mutect2, varscan2
- CUL2 | c.1732A>G p.T578A | Missense Mutation (SNP) | VAF 133/480 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.643); catalogued as COSV66079438; called by muse, mutect2, varscan2
- CUL9 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146080256; called by muse, mutect2, varscan2
- CUX1 | c.1664A>G p.Y555C (on ENST00000437600 / NM_181500.4; = p.Y557C on NM_001913.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52929073; called by muse, mutect2, varscan2
- CWC22 | c.1040T>C p.F347S | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55429205; called by muse, mutect2, varscan2
- CXCR2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs780840157, COSV59280944; called by muse, mutect2, varscan2
- CXXC1 | c.462T>A p.H154Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV53274924; called by muse, mutect2, varscan2
- CYBB | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV66085548; called by muse, mutect2, varscan2
- CYBRD1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 12/353 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1468545650, COSV100361404; called by muse, mutect2
- CYP11B2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs1563882431, COSV59996293; called by muse, mutect2, varscan2
- CYP21A2 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64480383; called by muse, mutect2, varscan2
- CYP46A1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55894962; called by muse, mutect2, varscan2
- CYRIA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs868184603, COSV62865285, COSV62865408; called by muse, mutect2, varscan2
- DAXX | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.73); catalogued as COSV56470110; called by muse, mutect2, varscan2
- DCAF13 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs756945539, COSV52572391; called by muse, mutect2, varscan2
- DCAKD | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1168925447, COSV60831385; called by muse, mutect2, varscan2
- DCBLD2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 131/406 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs763518499, COSV58790245; called by muse, mutect2, varscan2
- DCHS1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100202299; called by muse, mutect2
- DCLRE1A | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63748913; called by muse, mutect2, varscan2
- DCP1A | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs371414874; called by muse, mutect2, varscan2
- DCST1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs375462437; called by muse, mutect2, varscan2
- DDB1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57102944; called by muse, mutect2, varscan2
- DDX18 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV54307030; called by muse, mutect2, varscan2
- DDX24 | c.1274T>C p.M425T | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV58212710; called by muse, mutect2, varscan2
- DDX39A | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV99660394; called by muse, mutect2
- DDX46 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 180/547 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.905); catalogued as COSV62799555; called by muse, mutect2, varscan2
- DDX53 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV60068747; called by muse, mutect2, varscan2
- DDX60 | c.1722+1G>A p.X574_splice | Splice Site (SNP) | VAF 51/177 reads (29%) | catalogued as rs755907243, COSV67097115; called by muse, mutect2, varscan2
- DEGS2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs148474864; called by muse, mutect2, varscan2
- DELE1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs771820349, COSV52004911; called by muse, mutect2, varscan2
- DENND3 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52803032; called by muse, mutect2, varscan2
- DENND5B | c.2695C>T p.R899* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV60903341; called by muse, mutect2, varscan2
- DEPDC1 | c.1895A>C p.D632A (on ENST00000456315 / NM_001114120.3; = p.D348A on NM_017779.6) | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV63958442; called by muse, mutect2, varscan2
- DEPDC1 | c.381A>G p.I127M | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV63958446, COSV63958588; called by muse, mutect2, varscan2
- DEPDC1B | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54010711; called by muse, mutect2, varscan2
- DERL3 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99320316; called by muse, mutect2
- DGKD | c.848T>A p.L283Q (on ENST00000264057 / NM_152879.3; = p.L239Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV51053092; called by muse, mutect2, varscan2
- DGKZ | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs751670955, COSV58989684; called by muse, mutect2, varscan2
- DHRS11 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1344830295; called by muse, mutect2
- DHRS7 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 115/373 reads (31%) | catalogued as COSV53666281; called by muse, mutect2, varscan2
- DHX30 | c.560G>A p.R187Q (on ENST00000445061 / NM_138615.3; = p.R148Q on NM_014966.3) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.114); catalogued as rs779203311, COSV62395153; called by muse, mutect2, varscan2
- DHX30 | c.2495C>T p.A832V (on ENST00000445061 / NM_138615.3; = p.A793V on NM_014966.3) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.623); catalogued as rs1362064722, COSV53138459; called by muse, mutect2, varscan2
- DHX9 | c.3539A>G p.Y1180C | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.785); catalogued as COSV62360054; called by muse, mutect2, varscan2
- DIAPH3 | c.3191A>T p.N1064I (on ENST00000400324 / NM_001042517.2; = p.N801I on NM_030932.3) | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV57371789; called by muse, varscan2
- DIPK1B | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750606021, COSV63038101; called by mutect2, varscan2
- DIRAS1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568294994, COSV60215805; called by muse, mutect2, varscan2
- DKK1 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.431); catalogued as CM144339, COSV64760393; called by muse, mutect2, varscan2
- DLG3 | c.1657G>A p.G553R (on ENST00000374360 / NM_021120.4; = p.G216R on NM_020730.3) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1000766823, COSV52083323; called by muse, mutect2, varscan2
- DLG4 | c.875G>A p.R292Q (on ENST00000399506 / NM_001321075.3; = p.R335Q on NM_001365.4) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.384); catalogued as rs1337015053, COSV57238028; called by muse, mutect2, varscan2
- DLGAP1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59809227; called by muse, mutect2, varscan2
- DMRT2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as rs1428587897, COSV99426168; called by muse, mutect2
- DMRTB1 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs866444668, COSV65113242; called by muse, mutect2, varscan2
- DMXL1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV60710902; called by muse, mutect2, varscan2
- DMXL2 | c.6313G>A p.V2105I | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51848057; called by muse, mutect2, varscan2
- DNAH1 | c.3467A>G p.Y1156C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV70229944; called by muse, mutect2, varscan2
- DNAH1 | c.4973A>G p.Q1658R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV70229945; called by muse, mutect2, varscan2
- DNAH1 | c.7421G>A p.R2474H | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759951174, COSV70229948; called by muse, mutect2, varscan2
- DNAH10 | c.1002T>C p.G334= (on ENST00000409039; = p.G273= on NM_207437.3) | Splice Region (SNP) | VAF 102/361 reads (28%) | catalogued as COSV68995124; called by muse, mutect2, varscan2
- DNAH17 | c.9913G>T p.A3305S | Missense Mutation (SNP) | VAF 107/526 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV67756199; called by muse, mutect2, varscan2
- DNAH2 | c.6317G>A p.R2106H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1479540888, COSV66720676; called by muse, mutect2, varscan2
- DNAH8 | c.4604C>T p.A1535V | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546368; called by muse, mutect2
- DNAH8 | c.5866C>T p.R1956C | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773222614, COSV59452518; called by muse, mutect2, varscan2
- DNAJB14 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV62033925; called by muse, mutect2, varscan2
- DNAJC1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs143265965; called by muse, mutect2, varscan2
- DNAJC11 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 56/204 reads (27%) | catalogued as rs999766150, COSV53786833; called by muse, mutect2
- DNASE2 | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 121/368 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52248211; called by muse, mutect2, varscan2
- DNER | c.1406T>C p.I469T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs754654043, COSV59168347; called by muse, mutect2, varscan2
- DNM1L | c.1187T>G p.I396S | Missense Mutation (SNP) | VAF 146/500 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56774908; called by muse, mutect2, varscan2
- DOCK1 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs768105994, COSV99731201; called by muse, mutect2, varscan2
- DOCK10 | c.6110C>A p.S2037Y | Missense Mutation (SNP) | VAF 198/564 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV51417325; called by muse, mutect2, varscan2
- DOP1B | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1253886932, COSV67693736; called by muse, mutect2, varscan2
- DOT1L | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV67110328; called by muse, mutect2, varscan2
- DOT1L | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV67110335; called by muse, mutect2, varscan2
- DPF2 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 123/434 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52889184, COSV52889268; called by muse, mutect2, varscan2
- DPP9 | c.2107G>A p.E703K (on ENST00000598800; = p.E732K on NM_139159.5) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.523); catalogued as rs1273003179, COSV53591765; called by muse, mutect2, varscan2
- DRD1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.395); catalogued as COSV67104760; called by muse, mutect2, varscan2
- DSP | c.5413T>C p.C1805R | Missense Mutation (SNP) | VAF 93/283 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.364); catalogued as COSV65793270; called by muse, mutect2, varscan2
- DST | c.21326C>T p.T7109M (on ENST00000361203 / NM_001374722.1; = p.T4806M on NM_015548.5) | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747578451, COSV55019240; called by muse, mutect2, varscan2
- DUOX1 | c.3155A>G p.Y1052C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs779271658, COSV58482282; called by muse, mutect2, varscan2
- DUS3L | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs780880047, COSV57832181; called by muse, mutect2, varscan2
- DUSP16 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 138/426 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53807987; called by muse, mutect2, varscan2
- DYM | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs758432311, COSV53983159; called by muse, mutect2, varscan2
- DYNC1LI2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 219/681 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs761143885, COSV50754365; called by muse, mutect2, varscan2
- DYNC2H1 | c.5100G>T p.K1700N | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519098; called by muse, mutect2
- DYRK3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs959857675, COSV65606483; called by muse, mutect2, varscan2
- EDNRA | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 180/532 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1204047804, COSV60098176; called by muse, mutect2, varscan2
- EEF2 | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58579739; called by muse, mutect2, varscan2
- EEF2K | c.1415A>G p.E472G | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV53782740; called by muse, mutect2, varscan2
- EFCAB3 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59502507; called by muse, mutect2, varscan2
- EFNA5 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs199566187, COSV60951191; called by muse, mutect2, varscan2
- EIF4A1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV51511104; called by muse, mutect2, varscan2
- EIF4G3 | c.3810C>A p.S1270R | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684252; called by muse, varscan2
- ELF4 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV57452977; called by muse, mutect2, varscan2
- ELMO1 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60307530; called by muse, mutect2, varscan2
- EN1 | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54631435; called by muse, mutect2, varscan2
- ENO1 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV52304150; called by muse, mutect2, varscan2
- ENPP2 | c.2354G>A p.C785Y (on ENST00000075322 / NM_001040092.3; = p.C837Y on NM_006209.5) | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017585; called by muse, mutect2
- ENPP6 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV57068760; called by muse, mutect2, varscan2
- EOGT | c.1387G>A p.V463I (on ENST00000383701 / NM_001278689.2; = p.V379I on NM_173654.3) | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs764559304, COSV55149716; called by muse, mutect2, varscan2
- EP400 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57774919; called by mutect2, varscan2
- EP400 | c.6926T>C p.V2309A | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57774937; called by muse, mutect2, varscan2
- EPAS1 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV55387238; called by muse, mutect2, varscan2
- EPB41L2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 173/514 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370238340; called by muse, mutect2, varscan2
- EPHA10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs771803475, COSV60402406; called by muse, mutect2, varscan2
- EPHA5 | c.1910T>C p.F637S | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV56649477; called by muse, mutect2, varscan2
- EPHA7 | c.2402G>A p.R801K | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100994360, COSV65177462; called by muse, mutect2
- EPPK1 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs782743415, COSV73261521; called by muse, mutect2, varscan2
- EPS8L1 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99136711; called by muse, mutect2
- ERBB4 | c.2747T>A p.F916Y | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV61481366, COSV61494102; called by muse, mutect2, varscan2
- ERC1 | c.2447G>A p.R816Q (on ENST00000360905 / NM_178040.4; = p.R788Q on NM_178039.4) | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as rs376405419; called by muse, mutect2, varscan2
- ERGIC2 | c.1074T>C p.V358= | Splice Region (SNP) | VAF 101/341 reads (30%) | catalogued as COSV64112360; called by muse, mutect2, varscan2
- ERI3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV64830175; called by muse, mutect2, varscan2
- ERICH6 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 114/338 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV99901817; called by muse, mutect2
- ERMP1 | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs745308242, COSV53037731; called by muse, mutect2, varscan2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, mutect2, varscan2
- ETF1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62127451; called by muse, mutect2, varscan2
- ETNK2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs565275436, COSV65819905; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 136/410 reads (33%) | catalogued as COSV54136078; called by mutect2, varscan2
- ETV7 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775769716, COSV60317370; called by muse, mutect2, varscan2
- EVL | c.920C>T p.P307L (on ENST00000402714 / NM_001330221.2; = p.P309L on NM_016337.3) | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs151058458; called by muse, mutect2, varscan2
- EXTL2 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV64473105; called by muse, mutect2, varscan2
- EYA1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 120/367 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV58164674; called by muse, mutect2, varscan2
- F9 | c.142A>G p.N48D | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM000148, CM940405, COSV54380717; called by muse, mutect2, varscan2
- FAAP100 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs150686100; called by muse, mutect2, varscan2
- FAAP20 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV66031969; called by muse, varscan2
- FADS1 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 308/974 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV63520631; called by muse, mutect2, varscan2
- FAIM2 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100277625; called by muse, mutect2
- FAM111A | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV64655439; called by muse, mutect2, varscan2
- FAM149A | c.1117G>A p.A373T (on ENST00000356371 / NM_001367768.2; = p.A82T on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV57027915; called by muse, mutect2, varscan2
- FAM151A | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.373); catalogued as COSV56364544; called by muse, mutect2, varscan2
- FAM209A | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs1054339, COSV54765845; called by muse, mutect2, varscan2
- FAM47A | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.388); catalogued as COSV60497425; called by muse, mutect2, varscan2
- FAM9A | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.001); catalogued as COSV66812960; called by muse, mutect2, varscan2
- FANCA | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774863156, COSV59796943; called by muse, mutect2, varscan2
- FANCC | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs200719554, COSV100002312, COSV56661456; called by muse, mutect2, varscan2
- FASTK | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.499); catalogued as rs770526712, COSV52540407; called by muse, mutect2, varscan2
- FAT2 | c.12215G>A p.R4072H | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs374289322; called by muse, mutect2, varscan2
- FAT2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs752704380, COSV55817735; called by muse, mutect2, varscan2
- FBF1 | c.3280C>A p.H1094N (on ENST00000586717; = p.H1109N on NM_001319193.1) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV59865460; called by muse, mutect2, varscan2
- FBLN2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1415602625, COSV55485864; called by muse, mutect2, varscan2
- FBXL2 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as rs765529329, COSV52139500; called by muse, mutect2, varscan2
- FBXO15 | c.1318T>C p.C440R | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV54047356, COSV99503543; called by muse, mutect2
- FBXO47 | c.507+2T>C p.X169_splice | Splice Site (SNP) | VAF 65/212 reads (31%) | catalogued as COSV65241944; called by muse, mutect2, varscan2
- FCHO1 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV53183032; called by muse, mutect2, varscan2
- FCHSD2 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 12/321 reads (4%) | catalogued as COSV100238782; called by muse, mutect2
- FEV | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55386749; called by mutect2, varscan2
- FGD1 | c.2314G>A p.V772I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs373950992, COSV64308864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD2 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1346347817, COSV99236400; called by muse, mutect2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2, varscan2
- FGFR2 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs113014479, COSV60649219; called by muse, mutect2, varscan2
- FHOD1 | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770847586, COSV50761756; called by muse, mutect2, varscan2
- FHOD1 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs780244054, COSV50761800, COSV50770541; called by muse, mutect2, varscan2
- FILIP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as rs868698674, COSV52728473; called by muse, mutect2, varscan2
- FLG | c.6911C>T p.T2304I | Missense Mutation (SNP) | VAF 155/528 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV64242842; called by muse, mutect2, varscan2
- FLNB | c.1538T>C p.F513S | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV55881902; called by muse, mutect2, varscan2
- FLT4 | c.3039T>G p.D1013E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56111133; called by muse, mutect2, varscan2
- FLT4 | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV56111153; called by muse, mutect2, varscan2
- FMNL1 | c.3212T>C p.V1071A | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV58957356; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51931046; called by muse, mutect2, varscan2
- FNDC3B | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100394527; called by muse, mutect2
- FOXN3 | c.1339G>A p.E447K (on ENST00000261302; = p.E425K on NM_005197.4) | Missense Mutation (SNP) | VAF 136/391 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs780839699, COSV54310401; called by muse, mutect2, varscan2
- FRAS1 | c.2120G>T p.S707I | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53616826; called by muse, mutect2, varscan2
- FRAS1 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs775606687, COSV53591853; called by muse, mutect2, varscan2
- FRMPD2 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59718874; called by muse, mutect2, varscan2
- FRY | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.154); catalogued as rs781683553, COSV66569654; called by muse, mutect2, varscan2
- FRY | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs374747150; called by muse, mutect2, varscan2
- FRYL | c.5848C>T p.R1950* | Nonsense Mutation (SNP) | VAF 80/217 reads (37%) | catalogued as COSV51949609; called by muse, mutect2, varscan2
- FSD1 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV55696523; called by muse, mutect2, varscan2
- FSIP2 | c.18079A>G p.T6027A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV58088609; called by muse, mutect2, varscan2
- FTSJ3 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs145334305; called by muse, mutect2, varscan2
- FZD10 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 90/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57474005, COSV57474138; called by muse, mutect2, varscan2
- FZD3 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV53535869; called by muse, mutect2, varscan2
- GAB2 | c.1430T>A p.I477N (on ENST00000361507 / NM_080491.3; = p.I439N on NM_012296.3) | Missense Mutation (SNP) | VAF 113/385 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60868527; called by muse, mutect2, varscan2
- GABRB2 | c.943T>C p.F315L | Missense Mutation (SNP) | VAF 138/457 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV50915999; called by muse, mutect2, varscan2
- GABRG1 | c.1131+2T>C p.X377_splice | Splice Site (SNP) | VAF 51/141 reads (36%) | catalogued as COSV54955272; called by muse, mutect2, varscan2
- GAL3ST3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as rs371386420, COSV100360869; called by muse, mutect2, varscan2
- GALNT1 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV52452847; called by muse, mutect2, varscan2
- GALNT10 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51727858; called by muse, mutect2, varscan2
- GALR1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1026231983, COSV55317434; called by muse, mutect2, varscan2
- GATA5 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV53344990, COSV53346313; called by muse, mutect2, varscan2
- GATAD2A | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99390437; called by muse, mutect2
- GCM1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs374038938; called by muse, mutect2, varscan2
- GIMAP8 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs576578780, COSV56231919; called by muse, mutect2, varscan2
- GJB4 | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58356013, COSV58356351, COSV58357198; called by muse, mutect2, varscan2
- GLB1L | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 143/437 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs755869238, COSV55476985; called by muse, mutect2, varscan2
- GLI3 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 225/673 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as rs774754578, COSV67889423; called by muse, mutect2, varscan2
- GLOD4 | c.322T>C p.S108P (on ENST00000301328 / NM_001366247.1; = p.S93P on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56753795; called by muse, mutect2, varscan2
- GLUL | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.577); catalogued as rs776206110, COSV59382012, COSV59382271; called by muse, mutect2, varscan2
- GNAI2 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV56494326; called by muse, mutect2, varscan2
- GNPDA2 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV54946977; called by muse, mutect2, varscan2
- GOLGA3 | c.4255G>A p.A1419T | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs144728200; called by muse, mutect2, varscan2
- GOLGA5 | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV50833363; called by muse, mutect2, varscan2
- GP1BA | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56699732; called by muse, mutect2, varscan2
- GPR108 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99901442; called by muse, mutect2
- GPR141 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV57731496; called by muse, mutect2, varscan2
- GPR15 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV52520695; called by muse, mutect2, varscan2
- GPR156 | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1559929170, COSV59940483; called by muse, mutect2, varscan2
- GPR158 | c.3310G>A p.G1104R | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as rs368585897; called by muse, mutect2, varscan2
- GPR161 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773910892, COSV54791191; called by muse, mutect2, varscan2
- GPR20 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370642890; called by muse, mutect2
- GPR37 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV58256980; called by muse, mutect2
- GPR42 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751008926, COSV71995036; called by muse, mutect2, varscan2
- GPR68 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756196594, COSV53176160; called by muse, mutect2, varscan2
- GRB2 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV57305078; called by muse, mutect2, varscan2
- GREB1 | c.2326C>A p.L776I | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.814); catalogued as COSV52189085; called by muse, mutect2, varscan2
- GRIA3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.682); catalogued as rs1392959973, COSV52063686; called by muse, mutect2, varscan2
- GSK3A | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1205340289, COSV55899626; called by muse, mutect2, varscan2
- GTPBP2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1399993191, COSV61076147; called by muse, mutect2, varscan2
- GZMK | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs753500430, COSV50245500; called by muse, mutect2, varscan2
- H1-4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139427516; called by muse, varscan2
- H1-8 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as rs1210142720, COSV60714637; called by muse, mutect2, varscan2
- H2AC11 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV60362190, COSV60362474; called by muse, mutect2, varscan2
- H2AJ | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV63761923; called by muse, mutect2, varscan2
- H2BC3 | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 162/576 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as COSV63551093; called by muse, mutect2, varscan2
- H3-5 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1368563531, COSV61188012; called by muse, mutect2
- HACE1 | c.1678+2T>C p.X560_splice | Splice Site (SNP) | VAF 68/221 reads (31%) | catalogued as COSV53503238; called by muse, mutect2, varscan2
- HACL1 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV58254824; called by muse, mutect2, varscan2
- HBEGF | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50182659; called by muse, mutect2, varscan2
- HCFC1 | c.2351C>T p.T784M | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1557115352, COSV60071063; called by muse, mutect2, varscan2
- HCN1 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV57515450; called by muse, mutect2, varscan2
- HCN2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs773962337, COSV52115168; called by muse, mutect2, varscan2
- HCN3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs764867181, COSV100712850, COSV61361442; called by muse, mutect2, varscan2
- HDAC6 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as rs1569504759, COSV61929390; called by muse, mutect2, varscan2
- HDGFL1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV57752131; called by muse, mutect2, varscan2
- HDLBP | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 203/652 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60496889; called by muse, mutect2, varscan2
- HDLBP | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV60495715; called by muse, mutect2, varscan2
- HEATR1 | c.4210G>A p.D1404N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63981596; called by muse, mutect2, varscan2
- HECA | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.979); catalogued as COSV62769520; called by muse, mutect2, varscan2
- HECTD1 | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 128/392 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as COSV67946763; called by muse, mutect2, varscan2
- HECTD4 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 117/345 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs144116378; called by muse, mutect2, varscan2
- HECW1 | c.1285G>C p.G429R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.08); catalogued as COSV67831324; called by muse, mutect2, varscan2
- HECW1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368974637; called by muse, mutect2, varscan2
- HELZ2 | c.2454G>A p.W818* (on ENST00000467148 / NM_001037335.2; = p.W249* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV64409638; called by muse, mutect2, varscan2
- HENMT1 | c.379T>G p.L127V | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1416206419, COSV100898675; called by muse, mutect2
- HERC1 | c.7928C>T p.T2643M | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs756487485, COSV71247934, COSV71248166; called by muse, mutect2, varscan2
- HERC2 | c.10163A>T p.D3388V | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV55327687; called by muse, mutect2, varscan2
- HERC5 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV52039421; called by muse, mutect2, varscan2
- HHAT | c.641T>G p.L214* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV54800579; called by muse, mutect2, varscan2
- HHIPL1 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV58091169; called by muse, varscan2
- HIPK1 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.184); catalogued as rs370550902, COSV61248245; called by muse, mutect2, varscan2
- HIPK3 | c.2374A>G p.N792D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV57563045; called by muse, mutect2, varscan2
- HIVEP2 | c.1898G>T p.R633M | Missense Mutation (SNP) | VAF 15/397 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99174529; called by muse, mutect2
- HIVEP3 | c.6688A>G p.S2230G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.369); catalogued as COSV56016616; called by muse, mutect2
- HK2 | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 160/447 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV51876033; called by muse, mutect2, varscan2
- HLX | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as COSV65044964, COSV65045402; called by muse, mutect2, varscan2
- HMCN1 | c.2254C>A p.P752T | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.964); catalogued as COSV54906902; called by muse, mutect2, varscan2
- HMG20B | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99503136; called by muse, mutect2
- HNF1A | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421619915, COSV56567444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXD3 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV50881309; called by muse, mutect2, varscan2
- HPN | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs761123733, COSV52882373; called by muse, mutect2, varscan2
- HPS6 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV54625815; called by muse, mutect2, varscan2
- HPX | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56419610; called by muse, mutect2, varscan2
- HS3ST3A1 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948840702, COSV52378932; called by muse, mutect2
- HS3ST3B1 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62906710; called by muse, mutect2, varscan2
- HS3ST5 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV57145148; called by muse, mutect2
- HSD17B11 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs545124516, COSV64154500; called by muse, mutect2, varscan2
- HSD17B11 | c.375T>A p.Y125* | Nonsense Mutation (SNP) | VAF 105/378 reads (28%) | catalogued as COSV64154590; called by muse, mutect2, varscan2
- HSPA2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55969833; called by muse, mutect2, varscan2
- HSPA6 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59061211, COSV59061348; called by muse, mutect2, varscan2
- HSPG2 | c.10355G>A p.R3452Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1327754652, CM065276, COSV65933307; called by muse, mutect2, varscan2
- HSPG2 | c.8090G>A p.R2697Q | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); catalogued as rs757800931, COSV65972494; called by muse, mutect2, varscan2
- HYDIN | c.2251A>G p.T751A | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55487551; called by muse, mutect2, varscan2
- HYOU1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1336545313, COSV68216042; called by muse, varscan2
- IARS2 | c.3016G>A p.A1006T | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100228464; called by muse, mutect2
- IBTK | c.1627T>C p.S543P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs749743124, COSV60393424; called by muse, mutect2, varscan2
- ICAM2 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99856959; called by muse, mutect2
- ICAM5 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV55747544; called by muse, mutect2, varscan2
- IFI44L | c.1145G>A p.S382N | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60727949; called by muse, mutect2, varscan2
- IGBP1 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 177/534 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV60556522; called by muse, mutect2, varscan2
- IGLV3-10 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs376476919; called by muse, mutect2, varscan2
- IGSF10 | c.7115T>C p.I2372T | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV56381593; called by muse, mutect2, varscan2
- IGSF21 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV52135040; called by muse, mutect2, varscan2
- IGSF22 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60035155; called by muse, mutect2, varscan2
- IGSF8 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748591731, COSV58758297; called by muse, mutect2, varscan2
- IL11 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV52772815; called by muse, mutect2, varscan2
- IL12RB1 | c.1662del p.S555Afs*3 | Frame Shift Del (DEL) | VAF 31/259 reads (12%) | catalogued as COSV74045675; called by mutect2, pindel, varscan2
- IL12RB1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74045549; called by muse, mutect2, varscan2
- IL17RD | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756741660, COSV56339002; called by muse, mutect2, varscan2
- IL1RL2 | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51815994; called by muse, mutect2, varscan2
- IL7R | c.319A>T p.I107L | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as COSV57409243; called by muse, mutect2, varscan2
- ILDR1 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV56550613; called by muse, mutect2, varscan2
- INPP5F | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV62821795; called by muse, mutect2, varscan2
- INSL5 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs1220233937, COSV58788327; called by muse, mutect2, varscan2
- INSR | c.1679A>T p.D560V | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57164239, COSV57168815; called by muse, mutect2, varscan2
- INTS13 | c.1280T>C p.L427S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99677489; called by muse, mutect2
- INTS13 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1172573466, COSV53903057; called by muse, mutect2, varscan2
- INTS5 | c.2696A>G p.H899R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs766441275, COSV57952007; called by muse, mutect2, varscan2
- INTS6L | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 159/506 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66084639; called by muse, mutect2, varscan2
- INTU | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV56540308; called by muse, varscan2
- IQCN | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 117/335 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs752664961, COSV66574851; called by muse, mutect2, varscan2
- IQGAP1 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs780784277, COSV51586672; called by muse, mutect2, varscan2
- IRAG2 | c.4244G>A p.G1415D (on ENST00000636465; = p.G460D on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57232770; called by muse, mutect2, varscan2
- IRF1 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55375941; called by muse, mutect2
- IRF4 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV101110912; called by muse, mutect2
- IRX4 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 109/360 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51473119; called by muse, mutect2, varscan2
- ISX | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58087014; called by muse, mutect2, varscan2
- ITGA2B | c.1414G>A p.G472R | Missense Mutation (SNP) | VAF 119/375 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs375195998; called by muse, mutect2, varscan2
- ITGAE | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53995160; called by muse, mutect2
- ITGB8 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 151/510 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56006174; called by muse, mutect2, varscan2
- ITIH5 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1247790056, COSV56906234; called by muse, mutect2, varscan2
- ITPR2 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as rs772387642, COSV67268886; called by muse, mutect2, varscan2
- ITSN1 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101180593; called by muse, mutect2
- IVL | c.11A>G p.Q4R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV64216387; called by muse, mutect2, varscan2
- KANK1 | c.2602A>G p.S868G | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs748447539, COSV63212757; called by muse, mutect2, varscan2
- KANK4 | c.2012+1G>C p.X671_splice | Splice Site (SNP) | VAF 79/429 reads (18%) | catalogued as COSV62987219; called by muse, mutect2, varscan2
- KANK4 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1160902556, COSV62987225; called by muse, mutect2, varscan2
- KAT14 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs377501769; called by muse, mutect2, varscan2
- KATNIP | c.3949A>G p.K1317E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55182604; called by muse, mutect2, varscan2
- KCNA4 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV60252879; called by muse, mutect2, varscan2
- KCNC4 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202224349, COSV63926161; called by muse, mutect2
- KCNH7 | c.2890G>T p.G964W | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV59799287; called by muse, mutect2, varscan2
- KCTD3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as rs778860191, COSV52067393; called by muse, mutect2, varscan2
- KCTD5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs771536000, COSV57064855; called by muse, mutect2, varscan2
- KDF1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs755094201, COSV57671299; called by muse, mutect2, varscan2
- KDM3B | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100069971; called by muse, mutect2, varscan2
- KIAA1210 | c.4036A>G p.M1346V | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68177546; called by muse, mutect2, varscan2
- KIF13B | c.3841T>C p.F1281L | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.174); catalogued as rs775604707, COSV72954438; called by muse, mutect2, varscan2
- KIF13B | c.3102A>T p.E1034D | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV72954439; called by muse, mutect2, varscan2
- KIF18B | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59273631; called by muse, mutect2, varscan2
- KIF2B | c.1853A>G p.Q618R | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV52131411; called by muse, mutect2, varscan2
- KIFC1 | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV65729322; called by muse, mutect2, varscan2
- KIRREL1 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63287896; called by muse, mutect2, varscan2
- KIRREL2 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV52877135; called by muse, mutect2, varscan2
- KLHL1 | c.2204T>C p.I735T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV64773983; called by muse, mutect2, varscan2
- KLHL1 | c.495C>T p.H165= | Splice Region (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100917711; called by muse, mutect2
- KLHL17 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV58532175; called by muse, mutect2, varscan2
- KLHL34 | c.192A>T p.E64D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65279559; called by muse, mutect2, varscan2
- KLK1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs767774943, COSV56827308; called by muse, mutect2, varscan2
- KLK6 | c.131A>G p.H44R | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59565831; called by muse, mutect2, varscan2
- KMT2B | c.3856A>G p.T1286A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV55862646; called by muse, mutect2, varscan2
- KMT2B | c.6957C>T p.G2319= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as rs1290436845, COSV55862659; called by muse, mutect2, varscan2
- KMT2C | c.12632G>A p.R4211Q | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.946); catalogued as rs780271402, COSV51448966; called by muse, mutect2, varscan2
- KMT2D | c.6338T>C p.L2113P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV56420820; called by muse, mutect2, varscan2
- KMT2D | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375118713; called by muse, mutect2, varscan2
- KMT5B | c.1532G>T p.R511I | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58566778; called by muse, mutect2, varscan2
- KRT12 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs999519108, COSV52431127; called by muse, mutect2, varscan2
- KRT20 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV51425123; called by muse, mutect2, varscan2
- KRT75 | c.777C>T p.D259= | Splice Region (SNP) | VAF 100/280 reads (36%) | catalogued as rs373953042; called by muse, mutect2, varscan2
- KRTAP27-1 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV101239739; called by muse, mutect2, varscan2
- L1CAM | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62808200; called by muse, mutect2, varscan2
- L3MBTL2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.078); catalogued as rs148691612; called by muse, mutect2, varscan2
- LAMA1 | c.2290A>G p.T764A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV101057001; called by muse, mutect2
- LAMA2 | c.5643A>G p.I1881M | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1562531574, COSV70349613; called by muse, mutect2, varscan2
- LAMB2 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV59734316; called by muse, varscan2
- LCORL | c.5603C>T p.A1868V (on ENST00000635767 / NM_001365665.1; = p.G259= on NM_153686.8) | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1475640222, COSV52270742; called by muse, mutect2, varscan2
- LCP1 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 224/706 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); catalogued as COSV59941375; called by muse, mutect2, varscan2
- LCTL | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV58421428; called by muse, mutect2, varscan2
- LDHB | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV63364873; called by muse, mutect2, varscan2
- LGI1 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65058217; called by muse, mutect2, varscan2
- LGI4 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.448); catalogued as COSV59533886; called by muse, mutect2, varscan2
- LHFPL4 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV55002502; called by muse, mutect2, varscan2
- LILRA1 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 140/472 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV52181460; called by muse, varscan2
- LILRA4 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 78/287 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV52492589; called by muse, varscan2
- LIN9 | c.1409A>G p.N470S (on ENST00000366808 / NM_001270410.2; = p.N415S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/442 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60245418; called by muse, mutect2, varscan2
- LMAN1L | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs530877348, COSV59002239; called by muse, mutect2, varscan2
- LMAN1L | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs142493506; called by muse, mutect2, varscan2
- LMO7 | c.2104C>T p.R702C (on ENST00000357063; = p.R383C on NM_005358.5) | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370187434, COSV58538782; called by muse, mutect2, varscan2
- LMO7 | c.3923G>A p.R1308K (on ENST00000357063; = p.R989K on NM_005358.5) | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58538810; called by muse, mutect2, varscan2
- LMOD1 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as COSV100939224; called by muse, mutect2
- LONP1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV62262034; called by muse, mutect2, varscan2
- LOXL3 | c.1828T>C p.Y610H | Missense Mutation (SNP) | VAF 193/617 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777658017, COSV51208524; called by muse, mutect2, varscan2
- LOXL4 | c.1348T>C p.C450R | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53257177; called by muse, mutect2, varscan2
- LRIG2 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63162438; called by muse, mutect2, varscan2
- LRP1 | c.9905G>A p.S3302N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54514118; called by muse, mutect2, varscan2
- LRP1B | c.7726G>A p.D2576N | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1234683941, COSV67202828, COSV67230144; called by muse, mutect2, varscan2
- LRP2 | c.2716_2718del p.R906del | In Frame Del (DEL) | VAF 95/348 reads (27%) | catalogued as rs758132839; called by pindel, varscan2
- LRRC15 | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766289474, COSV61650362; called by muse, mutect2, varscan2
- LRRC37B | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 22/182 reads (12%) | catalogued as rs1391577583, COSV100496386; called by muse, mutect2
- LRRC59 | c.675G>A p.P225= | Splice Region (SNP) | VAF 127/367 reads (35%) | catalogued as rs746975375, COSV56814071; called by muse, mutect2, varscan2
- LRRC66 | c.2404C>A p.L802M | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV58634369; called by muse, mutect2, varscan2
- LRRC75B | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV50641107; called by muse, mutect2, varscan2
- LRRC8A | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.863); catalogued as rs1224174485, COSV52186311; called by muse, mutect2, varscan2
- LRRC8E | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs201947918, COSV60718358; called by muse, mutect2, varscan2
- LRRFIP1 | c.2188G>A p.E730K (on ENST00000392000 / NM_001137552.2; = p.E706K on NM_004735.4) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs536891978, COSV55252691; called by muse, mutect2, varscan2
- LRRTM2 | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 58/304 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51221136; called by muse, mutect2, varscan2
- LTBP1 | c.3719G>A p.R1240H (on ENST00000404816 / NM_206943.4; = p.R914H on NM_000627.4) | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs774371029, COSV55380279; called by muse, mutect2, varscan2
- LYN | c.168T>G p.F56L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV72923484; called by muse, mutect2, varscan2
- LYPD5 | c.313A>G p.T105A (on ENST00000377950 / NM_001031749.3; = p.T62A on NM_182573.2) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.091); catalogued as COSV65020734; called by muse, mutect2, varscan2
- LZTS2 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528162274, COSV64651808; called by muse, mutect2, varscan2
- MAEA | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53262935; called by muse, mutect2, varscan2
- MAP2 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs547929820, COSV52281438, COSV52293636; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs1476495251; called by mutect2, varscan2
- MAP3K11 | c.907A>G p.S303G | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58420098; called by muse, mutect2, varscan2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2, varscan2
- MAP4K2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs770950632, COSV53644331; called by muse, mutect2, varscan2
- MAP4K5 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 141/499 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs368497445, COSV50152507; called by muse, mutect2, varscan2
- MAP7D1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV60216731; called by muse, mutect2, varscan2
- MAP7D1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758768532, COSV100294635; called by muse, mutect2
- MARCO | c.1276A>T p.I426F | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV59055245; called by muse, mutect2, varscan2
- MASP1 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51460453; called by muse, mutect2, varscan2
- MATK | c.1165A>G p.K389E (on ENST00000310132 / NM_139355.3; = p.K390E on NM_002378.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59555118; called by muse, mutect2, varscan2
- MBD5 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1451851872, COSV101290173; called by muse, mutect2
- MC5R | c.214T>C p.Y72H | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61254852; called by muse, mutect2, varscan2
- MCM3AP | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52440696; called by muse, mutect2, varscan2
- MDH1B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs780661298, COSV65590123; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 48/138 reads (35%) | catalogued as rs750092100; called by mutect2, varscan2
- ME2 | c.1621T>C p.F541L | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58423528; called by muse, mutect2, varscan2
- MED12 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 125/417 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767396596, COSV61333102; called by muse, mutect2, varscan2
- MEGF10 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs377520032, COSV57255159; called by muse, mutect2
- MEGF6 | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs1343009518, COSV99620875; called by muse, mutect2
- MEGF8 | c.3302A>T p.H1101L (on ENST00000251268 / NM_001271938.2; = p.H1034L on NM_001410.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV52088193; called by muse, mutect2, varscan2
- MELK | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 24/1006 reads (2%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99974851; called by muse, mutect2
- MELK | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53199478; called by muse, mutect2, varscan2
- MEP1B | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV52497898; called by muse, mutect2, varscan2
- MEPCE | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52769332; called by muse, mutect2, varscan2
- METTL26 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100037483; called by muse, mutect2, varscan2
- METTL4 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV55248372; called by muse, mutect2, varscan2
- MFAP5 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV63945564; called by muse, mutect2, varscan2
- MFSD2A | c.895C>T p.R299W (on ENST00000372809 / NM_001136493.3; = p.R286W on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs373419262; called by muse, mutect2, varscan2
- MFSD2B | c.1027T>G p.F343V | Missense Mutation (SNP) | VAF 121/441 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57854950; called by muse, mutect2, varscan2
- MICAL3 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1016789692, COSV52898493; called by muse, mutect2, varscan2
- MICALL1 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766639546, COSV53241110; called by muse, mutect2, varscan2
- MICU2 | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66674240; called by muse, mutect2, varscan2
- MIER1 | c.691G>A p.A231T (on ENST00000355356 / NM_001077701.3; = p.A248T on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV62530645; called by muse, mutect2, varscan2
- MIF4GD | c.496A>G p.N166D (on ENST00000325102 / NM_001370592.1; = p.N200D on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV55453607; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs751180035; called by mutect2, varscan2
- MISP | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs762452224, COSV53120588; called by mutect2, varscan2
- MLH3 | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53135212; called by muse, mutect2, varscan2
- MLLT6 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs767514996; called by muse, mutect2, varscan2
- MN1 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV56558990; called by muse, mutect2, varscan2
- MOGAT2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52219965; called by muse, mutect2, varscan2
- MORN3 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 110/334 reads (33%) | catalogued as rs773975057, COSV62507453; called by mutect2, varscan2
- MPDZ | c.6050A>G p.K2017R (on ENST00000319217 / NM_001330637.2; = p.K1988R on NM_003829.5) | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100057194; called by muse, mutect2
- MPP7 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs773981675, COSV61733467; called by muse, mutect2, varscan2
- MRAP | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 114/317 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.42); catalogued as COSV57937082; called by muse, mutect2, varscan2
- MROH5 | c.1972A>G p.S658G | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71301770; called by muse, mutect2, varscan2
- MROH5 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV71301772; called by muse, mutect2, varscan2
- MROH8 | c.349A>G p.N117D | Missense Mutation (SNP) | VAF 119/413 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54120744; called by muse, mutect2, varscan2
- MROH9 | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV63011849; called by muse, mutect2, varscan2
- MRPL10 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV50109563; called by muse, mutect2, varscan2
- MS4A10 | c.757T>C p.W253R | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs368382320, COSV57632845; called by muse, mutect2, varscan2
- MSN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs373340100, COSV64304324; called by muse, mutect2, varscan2
- MSX2 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53327278, COSV53328184; called by muse, mutect2, varscan2
- MTG1 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV58154070; called by muse, mutect2, varscan2
- MTG1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs11553728, COSV58152885; called by muse, mutect2, varscan2
- MTHFD1 | c.2136G>A p.T712= | Splice Region (SNP) | VAF 31/109 reads (28%) | catalogued as rs150796086; called by muse, mutect2, varscan2
- MTMR10 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV58728493; called by muse, mutect2, varscan2
- MTMR7 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 131/392 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs553369647, COSV51666857; called by muse, mutect2, varscan2
- MUC6 | c.4112G>A p.G1371D | Missense Mutation (SNP) | VAF 76/1206 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.04); catalogued as rs746639344, COSV101424690; called by muse, mutect2
- MX1 | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 101/330 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV55819339; called by muse, mutect2, varscan2
- MYBPH | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs139911521; called by muse, mutect2, varscan2
- MYCBP2 | c.5051A>G p.K1684R (on ENST00000357337; = p.K1722R on NM_015057.5) | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV62022529; called by muse, mutect2, varscan2
- MYH11 | c.5212A>T p.I1738F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs951297859, COSV55555845; called by muse, mutect2, varscan2
- MYH11 | c.4703A>G p.N1568S | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55555867; called by muse, mutect2, varscan2
- MYH6 | c.5195T>A p.M1732K | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV62451527; called by muse, mutect2, varscan2
- MYH7 | c.5111A>G p.Q1704R | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV62520084; called by muse, mutect2, varscan2
- MYH7B | c.4262G>T p.S1421I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs760285059, COSV52680101, COSV52680767; called by muse, mutect2, varscan2
- MYO15A | c.1195T>C p.Y399H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs750617462, COSV52758325; called by muse, mutect2, varscan2
- MYO16 | c.3166T>C p.F1056L | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); catalogued as COSV62751497; called by muse, mutect2, varscan2
- MYO7B | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67348453; called by muse, mutect2, varscan2
- MYO9A | c.5783T>C p.L1928P | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV61852218; called by muse, mutect2, varscan2
- MYO9B | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV68279795; called by muse, mutect2, varscan2
- MYO9B | c.5732T>A p.L1911H | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV68279803; called by muse, varscan2
- MYOM1 | c.3527T>C p.V1176A | Missense Mutation (SNP) | VAF 107/320 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV55293281; called by muse, mutect2, varscan2
- MYOM1 | c.3046A>G p.M1016V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV55293298; called by muse, mutect2, varscan2
- MYOM3 | c.2356T>C p.S786P | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58395003; called by muse, varscan2
- MYT1L | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278344930, COSV101217070, COSV67702885; called by muse, mutect2, varscan2
- MYT1L | c.2747G>A p.G916D | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67719088; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 56/232 reads (24%) | catalogued as rs763929397; called by mutect2, varscan2
- NADK | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV58273136; called by muse, mutect2, varscan2
- NAPSA | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs749576537, COSV53796627; called by muse, mutect2, varscan2
- NAV1 | c.2744C>T p.T915I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55218819; called by muse, mutect2, varscan2
- NAV3 | c.5680G>A p.A1894T (on ENST00000397909 / NM_001024383.2; = p.A1872T on NM_014903.6) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57084984; called by muse, mutect2, varscan2
- NBEA | c.8224G>A p.G2742R | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100076171, COSV59790693; called by muse, mutect2, varscan2
- NCAPD2 | c.4091T>C p.V1364A | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV57521237; called by muse, mutect2, varscan2
- NCAPG | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 194/628 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52270734; called by muse, mutect2, varscan2
- NCAPH | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545991; called by muse, mutect2
- NCKAP1 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100720436; called by muse, mutect2
- NCKAP5 | c.4361C>T p.A1454V | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV58441311, COSV58448724; called by muse, varscan2
- NCKAP5 | c.4289G>T p.R1430M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV58448738; called by muse, varscan2
- NDE1 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775774594, COSV61273020; called by muse, mutect2, varscan2
- NDST1 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.287); catalogued as rs372636224, COSV55787960; called by muse, mutect2, varscan2
- NDUFS7 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs1052564692, CM165967, COSV52041035; called by muse, mutect2
- NDUFS7 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as COSV52039522; called by muse, mutect2, varscan2
- NEFM | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647339; called by muse, mutect2
1,171 further variants in this file (635 protein-altering or splice-affecting, 506 silent, 30 other) are not listed here.
